Gene-level copy-number profile of tumor specimen ALCH-B1S7-TTP1-A from ALCHEMIST case ALCH-B1S7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,483 days).
Specimen ALCH-B1S7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d3d418bd-e494-4328-b17a-6fb46bbd9294.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1S7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/b783e274-cd35-413b-8475-e099547c13af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,182; copy number 2: 51,015; copy number 3: 1,174; copy number 4: 10; copy number 10: 1; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–2): NOC2L.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr12:57,216,794–57,226,449, 1 gene: NXPH4.
- chr15:25,170,723–25,178,819, 5 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5.
- chr17:44,248,390–44,268,141, 1 gene: SLC4A1.
- chr20:3,777,504–3,812,434, 4 genes (within-gene range 0–1): SPEF1, CENPB, CDC25B, LINC01730.
- chr22:20,241,415–20,283,246, 2 genes (within-gene range 0–1): RTN4R, MIR1286.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,092,956–43,107,570, 1 gene, copy number 11: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 10–11: MRPL51P2, FRGCA.
- chr22:18,906,028–18,914,238, 1 gene, copy number 13 (within-gene range 2–13): DGCR6.

Autosomal genes at a single copy (total copy number 1): 6,182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
